Gene-level copy-number profile of specimen HCM-SANG-0275-C18-85A from HCMI case HCM-SANG-0275-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0275-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 673fefb3-97c6-4c5e-9cad-1d8b6790b826.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0275-C18-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/8369211e-a04e-4f26-b38f-458fbac51fe9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 894; copy number 2: 35,762; copy number 3: 18,517; copy number 4: 842; copy number 5: 2,832; copy number 7: 40; copy number 8: 6.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,064,389–12,177,550, 10 genes: DEFB130B, RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,878 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:722,092–724,903, 1 gene, copy number 5 (within-gene range 4–5): CICP3.
- chr1:12,938,472–13,032,130, 2 genes, copy number 5 (within-gene range 3–5): PRAMEF6, PRAMEF28P.
- chr1:13,172,455–13,179,464, 1 gene, copy number 5: PRAMEF9.
- chr5:4,436,850–4,440,259, 1 gene, copy number 5: AC106799.3.
- chr5:8,080,186–8,143,784, 2 genes, copy number 5: AC091941.1, AC091912.2.
- chr5:10,057,502–10,204,040, 10 genes, copy number 5: AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4.
- chr5:13,690,331–13,944,543, 2 genes, copy number 5 (within-gene range 4–5): DNAH5, AC016576.1.
- chr5:16,373,361–16,440,081, 2 genes, copy number 5: LINC02150, AC020980.1.
- chr5:16,473,038–16,617,058, 1 gene, copy number 5: RETREG1.
- chr5:16,617,225–16,623,095, 2 genes, copy number 5: AC022113.1, Y_RNA.
- chr5:17,490,967–17,502,363, 4 genes, copy number 5: H3Y2, AC106774.1, TAF11L2, H3P17.
- chr5:19,233,366–19,234,487, 1 gene, copy number 5: HSPD1P15.
- chr5:38,474,668–38,671,216, 3 genes, copy number 5: LIFR, LIFR-AS1, MIR3650.
- chr5:39,718,984–39,721,513, 1 gene, copy number 5: INTS6P1.
- chr5:40,066,651–40,067,200, 1 gene, copy number 5: KRT18P56.
- chr5:42,892,319–42,917,984, 4 genes, copy number 5: PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6.
- chr5:43,287,470–43,348,716, 3 genes, copy number 5: HMGCS1, AC114947.2, AC114947.1.
- chr5:44,495,099–45,696,498, 11 genes, copy number 5: LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1.
- chr8:40,114,651–89,243,793, 711 genes, copy number 5–8 (broad region; genes not listed).
- chr8:89,585,872–89,757,812, 1 gene, copy number 5 (within-gene range 4–5): AF117829.1.
- chr8:90,058,608–141,002,216, 674 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:140,940,562–145,066,685, 188 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–60,653,784, 1,252 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 894. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
